Somatic mutation profile of tumor specimen MMRF_2702_1_BM_CD138pos (aliquot MMRF_2702_1_BM_CD138pos_T1_KHS5U_L14426) from MMRF case MMRF_2702, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.7 years (22,518 days).
Specimen MMRF_2702_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a2591c7-103c-4e81-aaec-b0e239245dff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2702_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2702_1_PB_WBC_C2_KHS5U_L14427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10b27ea6-aa00-4a19-93a4-865f7be0c234

The open-access MAF lists 62 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 18, Missense Mutation 16, Silent 9, Intron 7, 5'UTR 3, Nonsense Mutation 2, 5'Flank 2, Splice Site 2, 3'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APCDD1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746141096, COSV100789937; called by muse, mutect2, varscan2
- ATG16L1 | c.186C>G p.D62E | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.103); catalogued as COSV100731293; called by muse, mutect2, varscan2
- HERC2 | c.1627G>C p.A543P | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV55344441; called by muse, mutect2, varscan2
- IGLV2-14 | c.154A>G p.N52D | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.019); catalogued as rs555923806; called by muse, mutect2, varscan2
- PRPH2 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1476970688; called by muse, mutect2, varscan2
- PTPRG | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs747031451; called by mutect2, varscan2
- SYNE1 | c.16392G>A p.V5464= (on ENST00000367255 / NM_182961.4; = p.V5393= on NM_033071.3) | Splice Region (SNP) | VAF 39/185 reads (21%) | catalogued as COSV54991877; called by muse, mutect2, varscan2
- TLN2 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs57294659; called by muse, mutect2, varscan2
- TRAF3 | c.245+1G>A p.X82_splice | Splice Site (SNP) | VAF 12/50 reads (24%) | catalogued as COSV61025221, COSV61027183; called by muse, mutect2, varscan2
- AQP1 | c.565T>C p.C189R | Missense Mutation (SNP) | VAF 144/427 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR3 | c.9311G>C p.C3104S | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2
- COL2A1 | c.587T>G p.L196W | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.221); called by muse, varscan2
- DST | c.2915A>C p.N972T (on ENST00000361203 / NM_001374722.1; = p.N646T on NM_001723.6) | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GLI1 | c.932C>G p.S311* | Nonsense Mutation (SNP) | VAF 58/312 reads (19%) | called by mutect2, varscan2
- IGLV2-14 | c.52T>G p.W18G | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- IGLV2-14 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.433); called by mutect2, varscan2
- KLHDC7A | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KRAS | c.176_178del p.A59del | In Frame Del (DEL) | VAF 12/84 reads (14%) | called by pindel, varscan2
- RNF213 | c.14966A>T p.H4989L | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC25A40 | c.97+2T>G p.X33_splice | Splice Site (SNP) | VAF 69/161 reads (43%) | called by muse, mutect2, varscan2
- SLFN5 | c.791T>A p.V264D | Missense Mutation (SNP) | VAF 51/414 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ZBTB8B | c.359C>G p.S120* | Nonsense Mutation (SNP) | VAF 15/281 reads (5%) | called by muse, mutect2
- ADAM19 | c.1032C>A p.A344= | Silent (SNP) | VAF 49/219 reads (22%) | called by muse, mutect2, varscan2
- CFAP46 | c.7587T>C p.S2529= | Silent (SNP) | VAF 31/176 reads (18%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.1185C>T p.T395= | Silent (SNP) | VAF 75/355 reads (21%) | catalogued as rs367958681; called by muse, mutect2, varscan2
- EFHB | c.1707C>G p.A569= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- HOGA1 | c.570G>A p.P190= | Silent (SNP) | VAF 29/156 reads (19%) | catalogued as rs1432672639; called by muse, mutect2, varscan2
- IGLV2-14 | c.153T>C p.Y51= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs370181175; called by muse, mutect2, varscan2
- TMEM176A | c.517A>C p.R173= | Silent (SNP) | VAF 30/92 reads (33%) | called by muse, mutect2, varscan2
- WDR11 | c.1755C>T p.V585= | Silent (SNP) | VAF 34/182 reads (19%) | catalogued as rs748143032; called by muse, mutect2, varscan2
- ZBTB41 | c.2022G>A p.K674= | Silent (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- ADAT3 | c.-110C>T | 5'UTR (SNP) | VAF 35/276 reads (13%) | catalogued as rs1370572503; called by muse, mutect2, varscan2
- ANTXR2 | chr4:80072601 C>T | 5'Flank (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- C5orf51 | c.*1117A>C | 3'UTR (SNP) | VAF 11/324 reads (3%) | called by muse, mutect2
- C8orf82 | c.*749G>T | 3'UTR (SNP) | VAF 13/296 reads (4%) | called by muse, mutect2
- C8orf82 | c.*747G>T | 3'UTR (SNP) | VAF 12/294 reads (4%) | called by muse, mutect2
- CAMK4 | c.*5296A>T | 3'UTR (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- COL5A2 | c.*1636T>C | 3'UTR (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- FER | c.1924+4485A>C | Intron (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- GMPPB | chr3:49717694 A>G | 3'Flank (SNP) | VAF 36/227 reads (16%) | called by muse, mutect2, varscan2
- GVQW3 | c.644+733C>A | Intron (SNP) | VAF 30/154 reads (19%) | catalogued as rs895019285; called by muse, mutect2, varscan2
- HDGF | chr1:156752299 T>C | 5'Flank (SNP) | VAF 83/397 reads (21%) | called by muse, mutect2, varscan2
- HOXA9 | c.*964T>A | 3'UTR (SNP) | VAF 57/137 reads (42%) | called by muse, mutect2, varscan2
- LDB2 | c.133-17G>C | Intron (SNP) | VAF 24/338 reads (7%) | called by muse, mutect2
- LRRC7 | c.647+36298T>A | Intron (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2, varscan2
- MARCHF4 | c.*180C>T | 3'UTR (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- MIEF1 | c.*1459T>C | 3'UTR (SNP) | VAF 29/123 reads (24%) | called by muse, mutect2, varscan2
- NUDCD3 | c.*1214C>T | 3'UTR (SNP) | VAF 31/263 reads (12%) | catalogued as rs943162232; called by muse, mutect2, varscan2
- NUDT4 | c.*8198_*8206del | 3'UTR (DEL) | VAF 25/154 reads (16%) | called by mutect2, pindel, varscan2
- PAX5 | c.*6876G>A | 3'UTR (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- PCDH15 | c.*1169G>C | 3'UTR (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- PDE6C | c.-127_-125dup | 5'UTR (INS) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- RGS4 | c.*1166G>T | 3'UTR (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- RUFY2 | c.-188G>T | 5'UTR (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- SPTA1 | c.*175A>C | 3'UTR (SNP) | VAF 13/103 reads (13%) | catalogued as COSV100778905; called by muse, mutect2, varscan2
- ST7 | c.151+66497T>C | Intron (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- TEX14 | c.4457+145T>C | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- TMX1 | c.*305T>A | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- TPD52L1 | c.*11C>T | 3'UTR (SNP) | VAF 28/125 reads (22%) | catalogued as rs369222385; called by muse, mutect2, varscan2
- TRIM11 | c.860-282del | Intron (DEL) | VAF 4/11 reads (36%) | called by muse*, mutect2
- WDTC1 | c.*743C>T | 3'UTR (SNP) | VAF 49/462 reads (11%) | called by muse, mutect2, varscan2
- ZNF260 | c.*2193C>A | 3'UTR (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
